Surgical pathology report (de-identified scan), TCGA case TCGA-ZD-A8I3, project TCGA-CHOL (Cholangiocarcinoma), tissue source site ILSbio, specimen TCGA-ZD-A8I3-01A (Primary Tumor).

[page 1 of 5]
IRB APPROVED

Form Revised

Clinical Case Report

(For Collection of Cancerous Tissue)

ICD-0-3

Cholangiocarcinoma 816013

Site intrahepatic bile duct
path C22.1

Lower C22.0
5/11/26/13

Informed Consent

I personally informed this patient that a specimen(s) would be collected to be used for research purposes. I reviewed the _____ with the patient and answered any questions the patient had. The patient then signed the consent form as a free and voluntary act. A copy of this informed consent document will be retained at our institution.

Name of Physician or Study Coordinator _____

Signature _____

Date _____

Clinical Information

GENERAL INFORMATION				
Date of Birth (mm/dd/yyyy)	Height	Marital Status	Race	Temperature
Gender	Weight	☐ Single ☒ Married	VIETNAMESE	
☐ Male ☒ Female		☐ Divorced ☐ Widow	Blood Pressure	Heart Rate

HISTORY OF PRESENT ILLNESS
Chief Complaints: Abdominal pain, fever, yellow skin
Symptoms: weight loss, fatigue
Clinical Findings:
Performance Scale (Karnofsky Score):
☐ 100 Asymptomatic ☐ 80-90 Symptomatic but Fully Ambulatory ☐ 60-70 Symptomatic, in bed less than 50% of day ☒ 40-50 Symptomatic, in bed more than 50% of day, but not bed ridden ☐ 20-30 Bed Ridden

CURRENT MEDICATIONS				
Drug	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 2 of 5]
PAST MEDICAL HISTORY			
Diagnosis/Disease/Disorder/Injury	Diagnosis Date	Treatment	Status

OB/GYN HISTORY			
Menopausal Status ☐ Pre-menopausal ☐ Peri-Menopausal ☐ Post-menopausal	Date of First Menses		# of Pregnancies
	_____ years old		# of Live Births
	Date of Last Menses		
Birth Control: ☐ Condom ☐ Oral Contraceptive ☒ IUD ☐ Other: _____			Hormone Replacement Therapy: _____

SOCIAL HISTORY				
Occupation:		Environmental Hazards:		
Smoking History				
Current Status	TYPE	Packs/day	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)
Alcohol Consumption				
Current Status	TYPE	Drinks/day	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)
Drug Use				
Current Status	TYPE	Frequency	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)

FAMILY MEDICAL HISTORY		
Relative	Diagnosis	Age of Diagnosis

LAB DATA					
Test	Result	Date	Test	Result	Date
HIV	☒ Negative ☐ Positive: _____		CEA	☐ Negative ☐ Positive: _____	
Hep B	☒ Negative ☐ Positive: _____		CA 15-3	☐ Negative ☐ Positive: _____	
Hep C	☒ Negative ☐ Positive: _____		CA 19-9	☐ Negative ☐ Positive: _____	
AFP	☐ Negative ☐ Positive: _____		PSA	☐ Negative ☐ Positive: _____	
Other:	☐ Negative ☐ Positive: _____		Other:	☐ Negative ☐ Positive: _____	
B/T Cell Markers: _____					

[page 3 of 5]
DIAGNOSTIC STUDIES		
Study	Results	Date
Ultrasound	A tumour was found in the liver	
X-Ray		
CT		
Endoscopy		
MRI		
Biopsy		

CLINICAL DIAGNOSIS		
Preoperative Clinical Diagnosis		
Liver Cancer		
Location of Suspected Involved Lymph Nodes	Location of Suspected Distant Metastasis	
Clinical Staging		Date of Diagnosis
T2 N0 M0 Stage: IB		

Treatment Information

SURGICAL TREATMENT			
Procedure			Date of Procedure
Resection of the right liver			
Primary Tumor			
Organ	Detailed Location	Size	
Liver Tumor	Right Liver	6 x 5 x 4cm	
Extension of Tumor			
Lymph Nodes			
Description	Location of Lymph Nodes	# of Lymph Nodes	
Palpable, Non-Dissected Lymph Nodes			
Dissected Lymph Nodes			
Distant Metastasis			
Organ	Detailed Location	Size	
Surgical Staging			
T2 N0 M0 Stage: IB			

NEOADJUVANT THERAPY (Chemo, Radiation, Immuno, Hormonal, or Molecular)				
Drug/Treatment	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 4 of 5]
Pathology Form

Specimen Information

Collected by: _____ Date: _____ Time: _____

Preserved by: _____ Date: _____ Time: _____

SPECIMEN TYPE (# of samples provided)							
Frozen		Paraffin Block		Blood/Serum/Plasma		Slide	
Diseased	Normal	Diseased	Normal	Diseased	Normal	Diseased	Normal
4	2	4	2			4	2
Time to LN2		Time to Formalin		Time to LN2			
12 min		13 min					

PATHOLOGICAL DESCRIPTION			
Primary Tumor			
Organ	Size	Extension of Tumor	Distance to NAT
Liver Tumor	6 x 5 x 4 cm	Right Liver	6 cm
Lymph Nodes			
Location	# Examined	# Metastasized	
Distant Metastasis			
Organ	Detailed Location	Size	
Pathological Staging			
pT 2 N 0 M 0		Stage: T2	
Notes:			

[page 5 of 5]
Consolidated Pathology Diagnosis

Cell Distribution		+	-	Structural Pattern		+	-
Diffuse			☒	Streaming			
Mosaic		☒		Storiform			
Necrosis		☒		Fibrosis			
Lymphocytic Infiltration		☒		Palisading			
Vascular Invasion			☒	Cystic Degeneration			
Clusterized		☒		Bleeding			
Alveolar Formation			☒	Myxoid Change			
Indian File			☒	Psammoma/Calcification			

Squamous	+	-	Adenomatous	+	-	Sarcomatous	+	-	Lymphomatous	+	-
Squamoid Cell			Glandular cell	☒		Round Cell			Large Cell		
Spindle Cell			Cell Stratification	☒		Fibroblast			Small Cell		
Keratin			Secretion	☒		Osteoblast			RS Cell/RS Like		
Desmosome			Intracyt. Vacuole	☒		Lipoblast			Inflam. Cell		
Pearl			Gland formation	☒		Myoblast			Plasma Cell		

Cellular Differentiation: ☐ Well ☐ Moderate ☒ Poor

Nuclear Atypia:	0	I	II	III
Aniso Nucleosis				☒
Hyperchromatism				☒
Nucleolar Prominent				☒
Multinucleated Giant Cell				☒
Mitotic Activity				☒

Nuclear Grade: 0 I II III

D1 107 D287 D3 753 D4 607

across 17

Final Pathology Report

Histological Diagnosis: cholesterol carcinoma **Grade:** 3

Comments:

Director, Research Pathology

Date

INTEGRATED REPORT OF FINDINGS BY COLLABORATORS AND

PATHOLOGISTS - FO

Source: NCI Genomic Data Commons file f5181c5c-4d60-4621-b2b7-289c88f80278 (TCGA-ZD-A8I3.0A18D59B-0D93-409E-8E7F-156B1C77964B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).